Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13S, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13S-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Right thyroid nodule. FNA suspicious of PTC.

Specimens Submitted:

1: SP: Thyroid, right lobe, lobectomy (fs)

DIAGNOSIS:

1. SP: Thyroid, right lobe, lobectomy (fs):

Tumor Type:

Papillary carcinoma, follicular variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.8 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

100-0-3

Carcinoma, Papillary w/ follicular variant

8340/3

Site: thyroid, NOS C73.9

for 11/14/10

[page 2 of 3]
Date of Procedure:

Date of Receipt:

Date of Report:

Billing Type:
Additional Copy to:

OUTPATIENT

Clinical Diagnosis & History:

Right thyroid nodule. FNA suspicious of PTC.

Specimens Submitted:

1: SP: Thyroid, right lobe, lobectomy (fs)

DIAGNOSIS:

1. SP: Thyroid, right lobe, lobectomy (fs):

Tumor Type:

Papillary carcinoma, follicular variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.8 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

[page 3 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1.) The specimen is received fresh for frozen section and is labeled "right thyroid lobe". It consists of a thyroid lobe measuring 4.5 x 2.5 x 1.8 cm and weighing 10.2 g. The surface is smooth and glistening. The lobe is inked black posterior and blue anterior. Serial sectioning reveals a well-circumscribed, tan-white nodule with a thin capsule measuring 1.8 x 1.8 x 1.7 cm. Portions of the nodule are submitted for frozen section and for TPS. The remainder of the specimen is entirely submitted.

Summary of sections:

FSC - frozen section control

N - nodule

RS - remaining sections

Summary of Sections:

Part 1: SP: Thyroid, right lobe, lobectomy (fs)

Block	Sect. Site	PCs
1	FSC	1
4	N	4
2	RS	2

1. SP: Right thyroid lobe (fs): Follicular lesion. Suspect papillary carcinoma, follicular variant.
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file e146da39-4e5e-4653-996b-1cd40de2b856 (TCGA-DJ-A13S.5568CCD4-25F8-4C94-93FC-17B1E8BF050A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).